Gene-level copy-number profile of tumor specimen HCM-SANG-0310-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0310-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0310-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 77b4f7d7-b95b-44fc-b067-b9003c00ccb3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0310-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/e2d0cf97-a7e3-45c3-9ae1-c118b7f7aaed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 28; copy number 2: 1,453; copy number 3: 616; copy number 4: 32,786; copy number 5: 4,630; copy number 6: 10,004; copy number 7: 3,333; copy number 8: 3,540; copy number 9: 593; copy number 10: 552; copy number 11: 564; copy number 12: 140; copy number 13: 60; copy number 14: 26; copy number 15: 2; copy number 18: 7; copy number 20: 4; copy number 21: 2; copy number 23: 3; copy number 28: 4; copy number 30: 3; copy number 52: 9.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:72,692,131–72,887,694, 5 genes (within-gene range 0–4): MCU, MIR4676, AC016542.3, AC016542.2, AC016542.1.
- chr15:20,803,505–20,940,333, 11 genes: AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1.
- chr17:18,450,244–18,475,920, 4 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,506,313, 1 gene: NOS2P2.
- chr20:15,280,764–15,280,873, 1 gene (within-gene range 0–6): RNA5SP475.
- chr22:18,615,581–18,653,617, 4 genes: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,969 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,150,898–164,899,296, 915 genes, copy number 9–14 (within-gene range 7–14) (broad region; genes not listed).
- chr1:205,913,048–206,023,909, 4 genes, copy number 9: SLC26A9, AL713965.1, RAB7B, CTSE.
- chr1:227,393,554–227,431,035, 1 gene, copy number 10 (within-gene range 8–10): LINC01641.
- chr1:227,430,526–232,041,272, 149 genes, copy number 10–13 (broad region; genes not listed).
- chr2:169,810,081–169,824,931, 1 gene, copy number 13 (within-gene range 4–13): METTL5.
- chr3:129,087,569–129,326,225, 14 genes, copy number 10: RAB43, ISY1-RAB43, AC108673.2, ISY1, AC108673.3, CNBP, RPS27P12, COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3.
- chr5:58,198–12,804,363, 238 genes, copy number 10 (broad region; genes not listed).
- chr5:40,240,167–41,510,628, 16 genes, copy number 13–23: LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3.
- chr7:5,592,816–5,606,655, 1 gene, copy number 12: FSCN1.
- chr7:7,293,508–7,293,880, 1 gene, copy number 13: AC079448.1.
- chr7:57,770,619–57,837,046, 13 genes, copy number 11: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:75,416,786–75,486,299, 1 gene, copy number 11 (within-gene range 7–11): POM121C.
- chr7:99,472,890–99,679,998, 10 genes, copy number 9: ZNF789, ZNF394, ZKSCAN5, FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25, AC005020.1, CYP3A5.
- chr8:114,791,653–137,105,458, 280 genes, copy number 9–11 (broad region; genes not listed).
- chr9:61,190,003–61,453,030, 7 genes, copy number 12: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:114,323,056–114,394,405, 3 genes, copy number 10: ORM1, ORM2, AKNA.
- chr12:38,078,529–38,329,721, 11 genes, copy number 11: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B.
- chr12:55,900,300–56,787,790, 65 genes, copy number 9 (broad region; genes not listed).
- chr13:29,764,371–31,332,276, 37 genes, copy number 10 (within-gene range 6–10): UBL3, Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, WDR95P, HSPH1, B3GLCT.
- chr13:43,908,669–44,256,596, 9 genes, copy number 10 (within-gene range 8–10): NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1.
- chr13:48,488,963–48,711,226, 6 genes, copy number 10: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2.
- chr13:57,204,379–57,204,799, 1 gene, copy number 18: MTCO2P3.
- chr13:73,036,401–73,227,260, 6 genes, copy number 9: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8.
- chr15:44,665,732–44,767,829, 4 genes, copy number 9: PATL2, Y_RNA, B2M, TRIM69.
- chr16:15,949,138–16,143,257, 1 gene, copy number 10 (within-gene range 6–10): ABCC1.
- chr16:18,781,295–19,718,235, 34 genes, copy number 12 (within-gene range 8–12): RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1.
- chr16:28,341,434–29,370,272, 1 gene, copy number 10 (within-gene range 8–10): AC009093.11.
- chr16:28,637,654–29,372,110, 46 genes, copy number 10: NPIPB8, AC145285.4, EIF3C, CDC37P1, MIR6862-2, AC145285.5, NPIPB9, AC145285.7, AC145285.2, AC145285.1, AC145285.3, AC145285.6, ATXN2L, AC133550.2, TUFM, MIR4721, SH2B1, AC133550.3, ATP2A1, ATP2A1-AS1, AC133550.1, RABEP2, CD19, NFATC2IP, AC109460.2, MIR4517, AC109460.1, SPNS1, AC109460.3, LAT, AC109460.4, NPIPB10P, AC009093.3, RRN3P2, AC009093.9, AC009093.8, AC009093.10, AC009093.2, AC009093.7, AC009093.1, AC009093.5, AC009093.4, AC009093.6, AC025279.1, AC025279.2, SNX29P2.
- chr16:46,842,632–46,851,254, 2 genes, copy number 15: CKBP1, AC007225.2.
- chr16:77,433,382–78,066,761, 12 genes, copy number 9 (within-gene range 8–9): AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr19:27,681,072–31,349,436, 64 genes, copy number 9–52 (within-gene range 6–52) (broad region; genes not listed).
- chr20:37,178,410–37,317,260, 3 genes, copy number 10 (within-gene range 6–10): RPN2, GHRH, MANBAL.
- chr20:49,113,339–49,188,367, 1 gene, copy number 9 (within-gene range 8–9): STAU1.
- chr20:49,219,295–49,568,137, 12 genes, copy number 9–12: DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
